Somatic mutation profile of tumor specimen TCGA-KL-8330-01A (aliquot TCGA-KL-8330-01A-11D-2310-10) from TCGA case TCGA-KL-8330, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 44.5 years (16,250 days).
Specimen TCGA-KL-8330-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbf03648-34e6-4ad0-bbce-d0923f5b5ae8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8330-11A (Solid Tissue Normal), aliquot TCGA-KL-8330-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20078dd5-4609-40fb-bd8a-7f838a771d67

The open-access MAF lists 23 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 15, Silent 3, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.6154C>T p.R2052* | Nonsense Mutation (SNP) | VAF 27/173 reads (16%) | catalogued as rs1465539150, COSV52191727; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 50/60 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as rs140980255, COSV52269719; called by muse, varscan2
- MTM1 | c.83A>G p.N28S | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs782634894; called by muse, mutect2, varscan2
- PPM1G | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1239643465, COSV59768338; called by muse, mutect2, varscan2
- SKI | c.1556G>T p.R519L | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs376322470; called by muse, mutect2, varscan2
- UGT2B7 | c.1375C>T p.R459* | Nonsense Mutation (SNP) | VAF 56/121 reads (46%) | catalogued as rs770419807, COSV59441898; called by muse, mutect2, varscan2
- UNC80 | c.1962+1G>T p.X654_splice | Splice Site (SNP) | VAF 11/29 reads (38%) | catalogued as COSV99781191; called by muse, mutect2, varscan2
- WDR81 | c.3440A>G p.K1147R (on ENST00000409644 / NM_001163809.2; = p.K96R on NM_152348.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100489298; called by muse, mutect2
- CD163 | c.1001C>A p.S334Y | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.972); called by muse, mutect2
- DST | c.15699A>T p.K5233N (on ENST00000361203 / NM_001374722.1; = p.K2821N on NM_015548.5) | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- GLB1L2 | c.289G>T p.V97F | Missense Mutation (SNP) | VAF 13/227 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MMP3 | c.1228A>C p.R410= | Splice Region (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
- MUC6 | c.3180G>C p.K1060N | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- NACC2 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RBM47 | c.1180dup p.R394Kfs*16 | Frame Shift Ins (INS) | VAF 28/118 reads (24%) | called by mutect2, pindel, varscan2
- RPH3A | c.287A>G p.N96S (on ENST00000389385 / NM_001143854.2; = p.N92S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RUFY3 | c.152C>A p.T51K | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- THOC2 | c.2918C>T p.T973I | Missense Mutation (SNP) | VAF 169/189 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- TUT7 | c.2974C>T p.P992S | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- ZNF445 | c.2729C>G p.T910S | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- KCNJ8 | c.1195C>A p.R399= | Silent (SNP) | VAF 50/354 reads (14%) | catalogued as COSV53715850; called by muse, mutect2, varscan2
- MYO5C | c.840C>T p.A280= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as rs780925357, COSV55902865; called by muse, mutect2, varscan2
- PCDHGC3 | c.1791C>T p.D597= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs1562065751, COSV52771056; called by muse, mutect2, varscan2
